Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1I0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1I0-06A (Metastatic).

SURGICAL PATHOLOGY REPORT

100-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9 3/12/11 *h*

Clinical History and Impression:
Recurrent melanoma.

Specimen(s) Received:
METASTATIC MELANOMA RIGHT SCAPULA

FINAL DIAGNOSIS

SKIN, RIGHT SCAPULA, EXCISION:

- METASTATIC MALIGNANT MELANOMA

Pathologist: M.D.
* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description: (M.D.; M.D.)
Received in formalin, labeled with the patient's name, MR#, and "metastatic melanoma right scapula," is an irregular unoriented skin wedge measuring 15.4 x 9.5 x 3.2 cm. The skin surface is tan-white with multiple circles on it. Underlying the circles are multiple nodules. The deep surface is muscle. Within the muscle are multiple nodules up to 3 cm in greatest dimension. These nodules are darkly pigmented. There is no scar or lesion visible on the skin surface. Gross photographs are taken. One aspect is arbitrarily designated 12 o'clock. The deep aspect is inked black. Perpendicular margins are taken for the clock face and sections of tumor to deep are taken. The tumor appears to involve the deep margin and two sections of tumor to skin are taken. Please see the included diagram. All together 18 cassettes are submitted. There is no scar or lesion visible on the skin surface.

Summary of Stains Performed and Reviewed Count
H&E, Recut, Serial 3

Summary of Tissue Submitted for Microscopic Examination Block Detail

Part 1] METASTATIC MELANOMA RIGHT SCAPULA	# Blocks	Designation	#	Description
	18	MARGIN	(12)	margin, perpendicular
		T DEEP	(4)	TUMOR TO DEEP
		T SKIN	(2)	TUMOR TO SKIN

Source: NCI Genomic Data Commons file c6f032bf-46c9-44c4-b975-8498ed320893 (TCGA-DA-A1I0.9221E424-4B17-4C47-8E62-8E6B588E8770.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).